Gene-level copy-number profile of tumor specimen TCGA-A6-5656-01B from TCGA case TCGA-A6-5656, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage I; Age at diagnosis: 74.4 years (27,184 days).
Specimen TCGA-A6-5656-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.6a200b55-070e-4c0e-a79f-e87af7b2fcf2.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A6-5656-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 401 have no estimate.
https://portal.gdc.cancer.gov/files/9cabea7b-4fa3-4b66-a91d-68923cb3b418

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 80; copy number 2: 59,162; copy number 3: 874; copy number 4: 62; copy number 5: 20; copy number 6: 3; copy number 7: 7; copy number 9: 5; copy number 11: 2; copy number 17: 1; copy number 19: 1; copy number 23: 2.
ABSOLUTE estimates for another vial of this sample (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A6-5656-01A-21D-A274-01): tumor purity 0.8, ploidy 2.14, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:120,035,033–120,040,615, 1 gene (within-gene range 0–2): AC097173.2.
- chr7:142,598,016–142,602,360, 2 genes: TRBV16, TRBV17.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 41 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:8,026,738–8,122,702, 2 genes, copy number 9 (within-gene range 2–9): AL034417.2, AL034417.1.
- chr4:139,114,930–139,115,374, 1 gene, copy number 6: PPP1R14BP3.
- chr5:140,200,163–140,203,187, 1 gene, copy number 7: AC011379.1.
- chr7:30,284,597–30,367,689, 3 genes, copy number 9 (within-gene range 2–9): ZNRF2, MIR550A1, MIR550B1.
- chr7:112,819,147–112,939,875, 1 gene, copy number 5 (within-gene range 2–5): BMT2.
- chr7:142,587,868–142,593,473, 2 genes, copy number 7: TRBV14, TRBV15.
- chr7:143,954,844–144,008,793, 5 genes, copy number 5 (within-gene range 2–5): OR2F1, CAPZA1P5, OR2Q1P, SLC16A1P1, OR6B1.
- chr7:144,069,811–144,075,870, 1 gene, copy number 11 (within-gene range 2–11): OR2A25.
- chr8:49,536,386–49,554,414, 1 gene, copy number 5: AC090155.1.
- chr9:64,621,560–64,652,556, 2 genes, copy number 23: AQP7P2, AL445665.1.
- chr10:118,004,916–118,046,941, 2 genes, copy number 5: RAB11FIP2, AC022395.1.
- chr12:18,424,663–18,425,140, 1 gene, copy number 5: AC092851.1.
- chr13:28,067,587–28,068,334, 1 gene, copy number 6: KATNBL1P1.
- chr13:48,316,863–48,320,475, 1 gene, copy number 17: PPP1R26P1.
- chr13:50,909,747–51,024,120, 1 gene, copy number 6 (within-gene range 2–6): RNASEH2B.
- chr14:38,973,399–38,987,383, 2 genes, copy number 5: AL132994.2, Y_RNA.
- chr15:25,054,210–25,062,427, 4 genes, copy number 7: SNORD116-2, SNORD116-3, SNORD116-4, SNORD116-5.
- chr15:25,239,838–25,257,027, 8 genes, copy number 5: SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44, AC124303.1.
- chr21:45,914,296–45,919,483, 1 gene, copy number 19: AJ239328.1.
- chr22:25,349,543–25,350,322, 1 gene, copy number 11: AL022324.2.

Autosomal genes at a single copy (total copy number 1): 59. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
